TCGA case TCGA-PN-A8MA — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Institute of Human Virology Nigeria. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/55add854-e63f-4335-bea9-23c3eb1e766a

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: Nigeria; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 43.6 years (15,918 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 13 days; Days to treatment end: 48 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 13 days; Days to treatment end: 48 days; Treatment dose: 54 Gy; Number of fractions: 27; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 3; Treatment outcome: Stable Disease; Chemo concurrent to radiation: Yes; Prescribed dose: 50; Prescribed dose units: mg; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment outcome: Stable Disease; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.

Follow-up (1 entry)
- Day 90 (adjuvant therapy): Disease response: With Tumor; ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User.
- Timepoint category: Initial Diagnosis; Weight: 71 kg; Height: 167 cm; BMI: 25.5.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-PN-A8MA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days; Initial weight: 80 mg.
  Slide TCGA-PN-A8MA-01A-01-DX1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-PN-A8MA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 8; Pregnancies count miscarriage: 1; Total pregnancy count: 9; Performance status other timing: during adjuvant therapy; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: No.
- Treatment, Radiation therapy info: Radiation treatment reason not completed: Adverse event/complications; Radiation therapy xrt type: External beam radiation.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 50mg; Chemo concurrent fractions total: 3.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 90 days; disease-specific survival: no event (censored), 90 days; progression-free interval: no event (censored), 90 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-PN-A8MA-01A-11D-A36I-01): tumor purity 0.78, ploidy 4.36, whole-genome doublings 2.
